Surgical pathology report (de-identified scan), TCGA case TCGA-QT-A69Q, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site University of North Carolina, specimen TCGA-QT-A69Q-01A (Primary Tumor).

SURGICAL PATHOLOGY

Case Number :

Diagnosis:

A: Adrenal gland, right, adrenalectomy

Histologic tumor type: pheochromocytoma

Tumor size (greatest dimension): 6.2 cm

Specimen integrity: intact

Specimen size: 6.9 x 5.2 x 3.1 cm

Invasive properties:

Capsule: not identified

Extra-adrenal tissues: not identified

Lymphovascular: not identified

Blood vascular: not identified

Histologic assessment of surgical margins: negative

Status of adrenal gland away from tumor: unremarkable

Lymph nodes:

Number of lymph nodes involved: 0

Number of lymph nodes examined: 1

Clinical History:

The patient is a -year-old man with biochemically proven pheochromocytoma of the right adrenal gland.

Gross Description:

Received is one appropriately labeled container, additionally labeled "right adrenal gland" and holds an estimated 75 gram, 6.9 x 5.2 x 3.1 cm adrenalectomy specimen. The outer surface is yellow, smooth, and inked green. Within the specimen there is a 6.2 x 5.0 x 4.8 cm tan/brown soft focally cystic mass. The mass originates within the medulla of the adrenal gland, occupies greater than 90% of the resection, and appears well-circumscribed. The normal appearing adrenal tissue is tan/yellow and the edge with a dark red/brown medulla. A portion of the mass is submitted to tissue procurement.

Block Summary:

A1-A7 - Representative sections of mass to include green inked outer surface

A8 - Representative section of uninvolved adrenal tissue

ICD-O-3
Pheochromocytoma,
malignant 8700/3
Site: Medulla of
adrenal gland C74.1
JW 5/16/13

Hist/Path Discrepancy		

Source: NCI Genomic Data Commons file d7b02e13-a256-459a-8122-3bdb671b788a (TCGA-QT-A69Q.A4780CBD-018D-46B2-878E-AEEF20996FB4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).